Somatic mutation profile of tumor specimen MMRF_1413_1_BM_CD138pos (aliquot MMRF_1413_1_BM_CD138pos_T1_KAS5U_L01703) from MMRF case MMRF_1413, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.6 years (26,137 days).
Specimen MMRF_1413_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31ed3325-bc94-429a-bd7d-93ba7e254498.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1413_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1413_1_PB_Whole_C2_KAS5U_L01711; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/145e3901-4da0-4b00-bd84-e2056da4bd41

The open-access MAF lists 147 somatic variants for this specimen: 61 protein-altering or splice-affecting, 20 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, 3'UTR 36, Silent 20, Intron 15, 5'UTR 7, 5'Flank 4, 3'Flank 2, RNA 2, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF2 | c.177G>C p.E59D | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs965854904; called by muse, mutect2, varscan2
- APCDD1 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.18); catalogued as rs779292945; called by muse, mutect2, varscan2
- AUTS2 | c.3755C>T p.T1252M | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs149469010; called by muse, mutect2, varscan2
- BAIAP3 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); catalogued as rs141741281; called by muse, mutect2, varscan2
- COG4 | c.13A>G p.M5V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as rs756277654; called by muse, mutect2, varscan2
- COL6A5 | c.2732G>T p.R911L | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55210582; called by muse, mutect2, varscan2
- DYRK1B | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs766454633; called by muse, mutect2
- EPHA3 | c.698A>G p.N233S | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs758441001; called by muse, mutect2, varscan2
- GLRB | c.839T>C p.I280T | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs1230470622; called by muse, mutect2, varscan2
- HGF | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 84/371 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs370760302; called by muse, mutect2, varscan2
- HMGXB3 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1262128281; called by muse, mutect2, varscan2
- IGHV4-39 | c.5A>C p.D2A | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); catalogued as rs587758577; called by muse, varscan2
- IGLV3-1 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 37/37 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774205851; called by muse, varscan2
- INTS1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 95/121 reads (79%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs752501215, COSV67180111; called by muse, mutect2, varscan2
- MAML3 | c.1693A>G p.T565A | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs536394392; called by muse, mutect2, varscan2
- MYBPC3 | c.2486T>C p.L829P | Missense Mutation (SNP) | VAF 97/157 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as rs1277271092; called by muse, mutect2, varscan2
- NGFR | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331306094; called by muse, mutect2, varscan2
- NYAP2 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as rs796728966; called by muse, mutect2
- PDZRN3 | c.2968C>T p.R990W | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs771793125, COSV55201434; called by muse, mutect2, varscan2
- REC114 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778339430, COSV58522912; called by muse, mutect2, varscan2
- RYR3 | c.3997C>T p.R1333C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs901274242, COSV66778867; called by muse, mutect2, varscan2
- SATB2 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53491625; called by muse, mutect2, varscan2
- SHANK3 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750249368; called by muse, mutect2
- SLC9A9 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1297654193; called by muse, mutect2, varscan2
- TAF1L | c.2929G>A p.G977R | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54268438; called by muse, mutect2
- TET2 | c.3575G>T p.G1192V | Missense Mutation (SNP) | VAF 90/337 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54402330; called by muse, mutect2, varscan2
- TLK1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1246533140, COSV62631084; called by muse, mutect2
- TYRP1 | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV66358449; called by muse, mutect2, varscan2
- ZAN | c.7828G>A p.D2610N | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.51); catalogued as COSV61814743; called by muse, mutect2, varscan2
- AKR1B10 | c.467C>G p.A156G | Missense Mutation (SNP) | VAF 57/82 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ANKRD31 | c.3976C>G p.L1326V | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.038); called by muse, mutect2
- ATP6V1A | c.1136G>A p.G379D | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- ATP9A | c.3074T>C p.L1025P | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CFAP58 | c.2047T>A p.F683I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNHD1 | c.11455A>C p.I3819L | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPP6 | c.1173C>A p.S391R (on ENST00000377770 / NM_001364500.2; = p.S329R on NM_001936.5) | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ENPP1 | c.2115_2126del p.E706_S709del | In Frame Del (DEL) | VAF 8/79 reads (10%) | called by mutect2, varscan2
- FAM162A | c.319A>G p.M107V | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FOXR2 | c.784A>G p.N262D | Missense Mutation (SNP) | VAF 50/50 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IGHV1-69D | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV4-39 | c.115A>C p.K39Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- IL18R1 | c.207C>A p.N69K | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- INTS6L | c.634A>C p.T212P | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- KCNE1 | c.146T>C p.M49T | Missense Mutation (SNP) | VAF 118/262 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- KLHL6 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LUZP2 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); called by muse, varscan2
- MIA3 | c.1442A>T p.D481V | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NID2 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NUP160 | c.4112T>C p.I1371T | Missense Mutation (SNP) | VAF 52/359 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- OR7C1 | c.305T>A p.F102Y | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PBX1 | c.338T>A p.L113* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- PCDHB5 | c.594A>C p.K198N | Missense Mutation (SNP) | VAF 101/141 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PPIL4 | c.383A>T p.E128V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SCART1 | c.1819G>T p.G607W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SF3A3 | c.912del p.K306Sfs*18 | Frame Shift Del (DEL) | VAF 24/38 reads (63%) | called by mutect2, varscan2
- SUCO | c.276T>G p.I92M | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.101); called by muse, mutect2
- TLR10 | c.1673A>G p.N558S | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- UBTFL1 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- XAGE2 | c.-8-1G>A | Splice Site (SNP) | VAF 35/181 reads (19%) | called by muse, mutect2, varscan2
- XBP1 | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN1 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- ANKRD28 | c.1128C>G p.L376= | Silent (SNP) | VAF 11/192 reads (6%) | called by muse, mutect2
- ANKRD55 | c.297C>T p.C99= | Silent (SNP) | VAF 44/74 reads (59%) | called by muse, mutect2, varscan2
- BICC1 | c.2433C>T p.S811= | Silent (SNP) | VAF 47/140 reads (34%) | catalogued as rs141637941; called by muse, mutect2, varscan2
- CORO2A | c.1416C>T p.F472= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as rs267602332, COSV59662690; called by muse, mutect2
- ERVV-1 | c.1143C>A p.V381= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as rs1005644672; called by muse, mutect2, varscan2
- IGHD3-22 | c.7C>T p.L3= | Silent (SNP) | VAF 8/8 reads (100%) | called by muse, mutect2
- IGLV3-25 | c.66G>A p.E22= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs376421895; called by muse, varscan2
- IGLV3-25 | c.99A>T p.P33= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs565609474; called by muse, varscan2
- MYH3 | c.2460C>A p.R820= | Silent (SNP) | VAF 9/177 reads (5%) | catalogued as COSV99878028; called by muse, mutect2
- OR52R1 | c.111G>A p.T37= | Silent (SNP) | VAF 39/65 reads (60%) | catalogued as rs773610816; called by muse, mutect2, varscan2
- PRR14L | c.3526T>C p.L1176= | Silent (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- RASSF1 | c.93G>C p.A31= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- RNF19B | c.373C>A p.R125= | Silent (SNP) | VAF 23/34 reads (68%) | called by muse, mutect2, varscan2
- STEAP2 | c.777A>G p.L259= | Silent (SNP) | VAF 12/289 reads (4%) | called by muse, mutect2
- TRBV7-4 | c.345A>G p.L115= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as rs761829361; called by muse, mutect2
- TRPV5 | c.399G>T p.V133= | Silent (SNP) | VAF 21/164 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.17508C>T p.G5836= (on ENST00000591111; = p.G4909= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as COSV59936654; called by muse, mutect2, varscan2
- ZDHHC8 | c.612T>G p.T204= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- ZNF536 | c.777G>A p.K259= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- ZNF823 | c.58T>C p.L20= | Silent (SNP) | VAF 79/358 reads (22%) | called by muse, mutect2, varscan2
- ABHD4 | chr14:22598056 T>C | 5'Flank (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- ADRA1D | c.*346G>T | 3'UTR (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- ALDH3A1 | c.-38G>A | 5'UTR (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- ATF6 | c.*2765T>C | 3'UTR (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- BASP1 | c.*662T>C | 3'UTR (SNP) | VAF 92/136 reads (68%) | called by muse, mutect2, varscan2
- BCAT2 | c.*31C>T | 3'UTR (SNP) | VAF 83/191 reads (43%) | called by muse, mutect2, varscan2
- CCDC187 | c.*2494_*2508del | 3'UTR (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel
- CCDC74B | c.*148A>G | 3'UTR (SNP) | VAF 87/304 reads (29%) | called by muse, mutect2, varscan2
- CLN8 | c.*4043C>T | 3'UTR (SNP) | VAF 40/67 reads (60%) | catalogued as rs1417772004; called by muse, mutect2, varscan2
- COL22A1 | c.*673T>G | 3'UTR (SNP) | VAF 29/41 reads (71%) | called by muse, mutect2, varscan2
- CPXM2 | c.*1C>A | 3'UTR (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- CSNK2A1 | c.*1244T>G | 3'UTR (SNP) | VAF 32/54 reads (59%) | called by muse, mutect2, varscan2
- DGKG | c.*1935G>A | 3'UTR (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- DUOX2 | c.2852-24C>A | Intron (SNP) | VAF 23/116 reads (20%) | called by muse, mutect2, varscan2
- EGFL8 | c.*152del | 3'UTR (DEL) | VAF 56/153 reads (37%) | catalogued as COSV100247019; called by mutect2, pindel, varscan2
- ERCC6L2 | c.2100+148A>G | Intron (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- EXOC3 | c.1776+107T>A | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- FBXL21P | n.934T>C | RNA (SNP) | VAF 56/209 reads (27%) | catalogued as rs373081190; called by muse, mutect2, varscan2
- GALNT10 | c.1056+2159C>A | Intron (SNP) | VAF 44/175 reads (25%) | called by muse, mutect2, varscan2
- GALNT10 | c.1056+2160C>G | Intron (SNP) | VAF 44/175 reads (25%) | called by muse, mutect2, varscan2
- HTR5A | c.-316G>C | 5'UTR (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- IFT122 | c.1851+17G>T | Intron (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- IGLC3 | c.*108A>G | 3'UTR (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- IL17A | c.-2C>G | 5'UTR (SNP) | VAF 155/443 reads (35%) | called by muse, mutect2, varscan2
- IQCE | c.-10C>T | 5'UTR (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- KLF11 | c.*1634_*1635del | 3'UTR (DEL) | VAF 34/85 reads (40%) | called by mutect2, pindel, varscan2
- KRTAP1-5 | c.*127A>G | 3'UTR (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- LHCGR | c.*302T>A | 3'UTR (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- LINC00303 | n.238C>A | RNA (SNP) | VAF 13/132 reads (10%) | catalogued as rs746843835; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851311 G>A | 5'Flank (SNP) | VAF 52/112 reads (46%) | catalogued as rs769465513; called by muse, mutect2, varscan2
- MKNK2 | c.*88G>A | 3'UTR (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- MUC17 | c.*454A>G | 3'UTR (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- MYBL1 | c.-290G>A | 5'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- NFKB1 | c.157-79A>C | Intron (SNP) | VAF 7/46 reads (15%) | called by muse, varscan2
- NOP9 | c.*3460C>T | 3'UTR (SNP) | VAF 8/62 reads (13%) | called by muse, varscan2
- NOS1AP | c.939+3601C>T | Intron (SNP) | VAF 11/18 reads (61%) | catalogued as rs533423999; called by muse, mutect2
- NOTCH2 | c.*3388dup | 3'UTR (INS) | VAF 14/70 reads (20%) | called by mutect2, varscan2
- NR1H2 | c.-1113_-1075del | 5'UTR (DEL) | VAF 29/55 reads (53%) | called by mutect2, pindel
- P2RY8 | c.*505T>A | 3'UTR (SNP) | VAF 68/79 reads (86%) | called by muse, mutect2, varscan2
- P3H2 | c.*795T>C | 3'UTR (SNP) | VAF 32/96 reads (33%) | called by muse, mutect2, varscan2
- PCSK1 | c.-191C>T | 5'UTR (SNP) | VAF 31/82 reads (38%) | catalogued as rs982200633; called by muse, mutect2, varscan2
- PDCD6 | chr5:271544 A>C | 5'Flank (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- PDE1B | c.*1394C>G | 3'UTR (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- PDHX | chr11:34916479 C>T | 5'Flank (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- PHOX2B | c.*1059C>T | 3'UTR (SNP) | VAF 76/206 reads (37%) | catalogued as rs1474488805; called by muse, mutect2, varscan2
- PTGS2 | c.*2210del | 3'UTR (DEL) | VAF 102/199 reads (51%) | catalogued as rs1481019136; called by mutect2, pindel, varscan2
- PXYLP1 | c.80-4183G>A | Intron (SNP) | VAF 40/126 reads (32%) | called by muse, mutect2, varscan2
- RABIF | c.*1512A>G | 3'UTR (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- RCC1L | c.584-46T>C | Intron (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- RHAG | c.*47C>A | 3'UTR (SNP) | VAF 12/360 reads (3%) | called by muse, mutect2
- RIMKLB | c.*1889G>T | 3'UTR (SNP) | VAF 102/103 reads (99%) | called by muse, mutect2, varscan2
- RPS14 | chr5:150444137 A>G | 3'Flank (SNP) | VAF 11/157 reads (7%) | called by muse, mutect2
- SLC17A6 | c.891+45C>T | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as rs541494682; called by muse, mutect2, varscan2
- SLC23A2 | c.*2194G>T | 3'UTR (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- SLIT3 | c.2720-82A>T | Intron (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- STX1A | c.358-15A>G | Intron (SNP) | VAF 43/167 reads (26%) | called by muse, mutect2, varscan2
- TCF7L2 | c.*252G>T | 3'UTR (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- TENT5C | c.*1295T>G | 3'UTR (SNP) | VAF 4/32 reads (13%) | catalogued as COSV101033091; called by muse, mutect2, varscan2
- TLE3 | c.*169G>A | 3'UTR (SNP) | VAF 46/183 reads (25%) | called by muse, mutect2, varscan2
- TNKS | c.673+790_673+791insGTT | Intron (INS) | VAF 28/90 reads (31%) | called by pindel, varscan2
- TPM3 | chr1:154157066 G>A | 3'Flank (SNP) | VAF 22/85 reads (26%) | called by mutect2, varscan2
- TRAF2 | c.*377G>T | 3'UTR (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- UNC5C | c.*3157A>C | 3'UTR (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- UPRT | c.*462C>G | 3'UTR (SNP) | VAF 5/28 reads (18%) | called by mutect2, varscan2
- USP37 | c.*724A>G | 3'UTR (SNP) | VAF 53/178 reads (30%) | called by muse, mutect2, varscan2
- ZNF496 | c.893-73T>G | Intron (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
